Gene-level copy-number profile of tumor specimen ALCH-B3ZL-TTR1-A from ALCHEMIST case ALCH-B3ZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,038 days).
Specimen ALCH-B3ZL-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efddbcdb-d53a-48a6-86bf-0993e968d907.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/1e3e7265-b228-45d8-b535-151045b5bbb9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 21,912; copy number 2: 31,115; copy number 3: 4,990; copy number 4: 156; copy number 5: 145; copy number 6: 21; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–49,293,485, 23 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1.
- chr15:25,213,648–25,225,284, 7 genes (within-gene range 0–1): SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:44,825,747–45,167,526, 21 genes (within-gene range 0–1): SORD2P, AC122108.1, Y_RNA, RNU1-119P, AC090888.3, AC090888.1, RNU6-1108P, TERB2, RNU6-1332P, AC090888.2, RNU6-966P, RNU1-78P, SORD, AC091117.2, Y_RNA, AC091117.1, DUOX2, DUOXA2, DUOXA1, DUOX1, AC051619.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 169 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,783,354–9,556,520, 22 genes, copy number 5 (within-gene range 2–5): MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3.
- chr8:9,899,871–9,906,678, 2 genes, copy number 5: MIR124-1HG, MIR124-1.
- chr8:11,676,959–11,896,870, 8 genes, copy number 5: GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1.
- chr8:12,696,307–12,811,478, 7 genes, copy number 5 (within-gene range 3–5): OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1.
- chr8:20,079,114–20,226,819, 4 genes, copy number 5: AC100802.1, RPL30P9, SLC18A1, ATP6V1B2.
- chr8:29,632,091–29,748,109, 2 genes, copy number 5: RPL17P33, LINC00589.
- chr8:36,277,763–36,779,209, 8 genes, copy number 5 (within-gene range 3–5): MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10.
- chr8:42,271,302–42,405,937, 5 genes, copy number 6: IKBKB, POLB, RPL5P23, DKK4, VDAC3.
- chr8:43,292,483–43,674,591, 14 genes, copy number 5: POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:48,515,852–48,921,740, 10 genes, copy number 5: AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2.
- chr8:61,500,556–61,944,180, 7 genes, copy number 5 (within-gene range 1–5): ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1.
- chr8:73,420,369–74,208,536, 21 genes, copy number 5 (within-gene range 1–5): STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1.
- chr8:98,102,344–98,159,835, 2 genes, copy number 6: RIDA, POP1.
- chr8:102,805,517–102,810,039, 1 gene, copy number 6: GASAL1.
- chr8:117,794,490–118,111,826, 1 gene, copy number 5: EXT1.
- chr8:119,711,830–120,373,573, 11 genes, copy number 5: RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:124,811,042–125,367,120, 13 genes, copy number 6 (within-gene range 3–6): AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2.
- chr8:133,946,677–133,963,259, 2 genes, copy number 5: AC110741.3, AC110741.2.
- chr8:134,477,788–134,979,279, 16 genes, copy number 5: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr11:1,157,953–1,201,138, 1 gene, copy number 5: MUC5AC.
- chr14:26,443,090–27,845,286, 12 genes, copy number 5–8: NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171.

Autosomal genes at a single copy (total copy number 1): 20,484. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
